Somatic mutation profile of tumor specimen TCGA-36-2534-01A (aliquot TCGA-36-2534-01A-01D-1526-09) from TCGA case TCGA-36-2534, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.9 years (26,621 days).
Specimen TCGA-36-2534-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d02e7c78-57df-4808-bb76-6c42b3e05112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2534-10A (Blood Derived Normal), aliquot TCGA-36-2534-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9ebd4fa-2ee7-4fb8-9c1c-ec4ca0907684

The open-access MAF lists 150 somatic variants for this specimen: 120 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 28, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 4, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs281875302, CM032829, CM125036, COSV100747234; ClinVar: not provided / likely pathogenic; called by muse, mutect2
- BRCA1 | c.5278-1G>T p.X1760_splice | Splice Site (SNP) | VAF 376/414 reads (91%) | catalogued as rs80358099, CS021726, CS971624, CS973718, COSV58789769; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7063-1G>T p.X2355_splice (on ENST00000358273 / NM_001042492.3; = p.X2334_splice on NM_000267.3) | Splice Site (SNP) | VAF 19/94 reads (20%) | catalogued as rs1131691114, CS1311547, CS1512942, COSV62200723, COSV62204963, COSV62210858; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 240/292 reads (82%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ABL1 | c.3253G>C p.E1085Q | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59331317, COSV59332375; called by muse, mutect2, varscan2
- ACSM3 | c.1399A>G p.K467E | Missense Mutation (SNP) | VAF 122/435 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55499843, COSV55501625; called by muse, mutect2, varscan2
- ADAMTS15 | c.2092T>A p.F698I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100143823; called by muse, mutect2
- ADCY2 | c.3218C>T p.T1073M | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57860219; called by muse, mutect2, varscan2
- ADRB3 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV61461881; called by muse, mutect2, varscan2
- AHNAK | c.3755T>G p.L1252R | Missense Mutation (SNP) | VAF 104/1044 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99949758; called by muse, mutect2, varscan2
- AP3M2 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as COSV51529012; called by muse, mutect2, varscan2
- APOBEC4 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58017610, COSV58017694; called by muse, mutect2, varscan2
- ARF5 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs773554378, COSV50000329; called by muse, mutect2, varscan2
- ARHGAP15 | c.310A>G p.T104A | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.64); PolyPhen benign (0.101); catalogued as rs1030218974, COSV54497431; called by muse, mutect2, varscan2
- ARHGAP17 | c.1653C>A p.S551R | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV51507678; called by muse, mutect2, varscan2
- AWAT2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99339799; called by muse, mutect2
- AZGP1 | c.790T>G p.S264A | Missense Mutation (SNP) | VAF 169/397 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1284798031, COSV52797952; called by muse, mutect2, varscan2
- AZU1 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV52141111; called by muse, mutect2, varscan2
- BTAF1 | c.328A>G p.R110G | Missense Mutation (SNP) | VAF 163/364 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV56434492; called by muse, mutect2, varscan2
- C16orf72 | c.105C>G p.D35E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767985529, COSV59916092; called by muse, varscan2
- CACNA1S | c.5411C>T p.A1804V | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV100755405; called by muse, mutect2
- CACNG3 | c.685T>A p.Y229N | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV50069097; called by muse, mutect2, varscan2
- CARD6 | c.129G>C p.E43D | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780084390, COSV54566393; called by muse, mutect2, varscan2
- CD200R1 | c.847G>T p.V283F (on ENST00000471858 / NM_170780.3; = p.V306F on NM_138806.4) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV55601016; called by muse, mutect2, varscan2
- CD22 | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99323802; called by muse, mutect2
- CFTR | c.257T>A p.I86N | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99140065; called by muse, mutect2
- CLIP2 | c.1142A>T p.E381V | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56279358; called by muse, varscan2
- COL27A1 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 260/644 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61926493; called by muse, mutect2, varscan2
- CROCC | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV65012242; called by muse, mutect2, varscan2
- CSK | c.1084-1G>C p.X362_splice | Splice Site (SNP) | VAF 18/308 reads (6%) | catalogued as COSV99583958; called by muse, mutect2
- CTSG | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV53535591; called by muse, varscan2
- DDI1 | c.628del p.A210Lfs*5 | Frame Shift Del (DEL) | VAF 51/114 reads (45%) | catalogued as COSV100157858; called by mutect2, pindel, varscan2
- DDX46 | c.2363C>G p.A788G | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.416); catalogued as COSV62799440; called by muse, mutect2, varscan2
- DHRS9 | c.492T>G p.S164R | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100513710; called by muse, mutect2
- DLK1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.761); catalogued as rs888726734, COSV57991708; called by muse, mutect2, varscan2
- DOCK5 | c.4942G>T p.E1648* | Nonsense Mutation (SNP) | VAF 211/279 reads (76%) | catalogued as COSV104371739, COSV52402603; called by muse, mutect2, varscan2
- EFS | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as rs774043832, COSV53732550; called by muse, mutect2, varscan2
- EIF2B4 | c.1469A>C p.D490A (on ENST00000347454 / NM_001034116.2; = p.D489A on NM_015636.3) | Missense Mutation (SNP) | VAF 182/411 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61457147; called by muse, mutect2, varscan2
- ELOVL2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867506828, COSV61155340; called by muse, mutect2, varscan2
- EML3 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 168/392 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV53906785; called by muse, mutect2, varscan2
- ENPP5 | c.1005G>T p.L335= | Splice Region (SNP) | VAF 242/485 reads (50%) | catalogued as COSV57908828; called by muse, mutect2, varscan2
- EPYC | c.211A>C p.T71P | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1162197490, COSV99664927; called by muse, mutect2
- EQTN | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 136/287 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1413785073, COSV66218944, COSV66219426; called by muse, mutect2, varscan2
- ETFA | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 289/335 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV51211594; called by muse, mutect2, varscan2
- FAM110B | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as rs1486820775, COSV64065369; called by muse, mutect2, varscan2
- FAM149A | c.1927G>A p.V643M (on ENST00000356371 / NM_001367768.2; = p.V352M on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 195/449 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs149087810; called by muse, mutect2, varscan2
- FKBP9 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.26); catalogued as COSV99640511; called by muse, mutect2
- GABBR2 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52304716; called by muse, mutect2, varscan2
- GGA2 | c.509A>T p.D170V | Missense Mutation (SNP) | VAF 295/1015 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as rs1567364599, COSV59168367, COSV59168721; called by muse, mutect2, varscan2
- GTF2IRD2 | c.667T>A p.S223T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); catalogued as COSV63100382; called by mutect2, varscan2
- H2BC17 | c.129C>G p.Y43* | Nonsense Mutation (SNP) | VAF 433/1002 reads (43%) | catalogued as rs915712206, COSV58152760; called by muse, mutect2, varscan2
- HAPLN4 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV52269636; called by muse, mutect2, varscan2
- HCN1 | c.1736T>G p.M579R | Missense Mutation (SNP) | VAF 27/351 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100298878, COSV100302536; called by muse, mutect2
- HOXA13 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 122/266 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); catalogued as COSV56083441; called by muse, varscan2
- HYAL4 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV56138731; called by muse, mutect2, varscan2
- IFIH1 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV55126951, COSV55129041; called by muse, mutect2, varscan2
- IGSF3 | c.3322G>A p.V1108I (on ENST00000369486 / NM_001007237.3; = p.V1128I on NM_001542.4) | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as rs979490438, COSV59591192; called by muse, mutect2, varscan2
- INIP | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 316/641 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV65295531; called by muse, mutect2, varscan2
- ITFG2 | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 140/305 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57389744; called by muse, mutect2, varscan2
- ITGAE | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 178/230 reads (77%) | SIFT tolerated (0.42); PolyPhen benign (0.266); catalogued as COSV53994573; called by muse, mutect2, varscan2
- ITPK1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs201410742; called by muse, mutect2, varscan2
- KLB | c.1748A>C p.K583T | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV57302033; called by muse, mutect2, varscan2
- LIPC | c.628T>A p.S210T | Missense Mutation (SNP) | VAF 320/355 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54422955; called by muse, mutect2, varscan2
- LONRF3 | c.1580T>A p.I527K (on ENST00000371628 / NM_001031855.3; = p.I486K on NM_024778.5) | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59152541; called by muse, mutect2, varscan2
- LRRC56 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 70/94 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV54240684, COSV54241554; called by muse, mutect2, varscan2
- MAST3 | c.1274C>G p.P425R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99446378; called by muse, mutect2
- MATN1 | c.1380C>A p.C460* | Nonsense Mutation (SNP) | VAF 157/252 reads (62%) | catalogued as COSV65650691; called by muse, mutect2, varscan2
- MED20 | c.289A>C p.K97Q | Missense Mutation (SNP) | VAF 178/417 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV54825198; called by muse, mutect2, varscan2
- MEIS3 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58983657; called by muse, mutect2, varscan2
- MIDEAS | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as COSV54095135; called by muse, mutect2, varscan2
- MUC17 | c.11069G>A p.S3690N | Missense Mutation (SNP) | VAF 219/500 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.77); catalogued as COSV60289714; called by muse, mutect2, varscan2
- MYH1 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV56849140; called by muse, mutect2, varscan2
- MYLIP | c.1172G>T p.C391F | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62766861; called by muse, mutect2, varscan2
- MYLK2 | c.1710+1G>A p.X570_splice | Splice Site (SNP) | VAF 61/180 reads (34%) | catalogued as COSV65659121; called by muse, mutect2, varscan2
- NAE1 | c.1438C>G p.H480D | Missense Mutation (SNP) | VAF 116/133 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs11556608, COSV51976538; called by muse, mutect2, varscan2
- NFAT5 | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV63027754; called by muse, mutect2, varscan2
- NOTCH2 | c.5227C>G p.Q1743E | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV56692277; called by muse, mutect2, varscan2
- NUP35 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.072); catalogued as COSV99717956; called by muse, mutect2
- OCM2 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 336/837 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201256816, COSV57535376; called by muse, mutect2, varscan2
- OR13A1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 69/76 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs201230704, COSV65572495; called by muse, mutect2, varscan2
- OR1M1 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV70036928; called by muse, mutect2, varscan2
- OR51S1 | c.505T>A p.F169I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV100437594; called by muse, mutect2
- OVOL1 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60119895; called by muse, mutect2, varscan2
- PCDHA6 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.152); catalogued as rs1554131491, COSV100972566; called by muse, mutect2
- PIGG | c.2596G>A p.V866M (on ENST00000453061 / NM_001127178.3; = p.V858M on NM_017733.4) | Missense Mutation (SNP) | VAF 145/193 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs140960241, COSV56318241; called by muse, mutect2, varscan2
- PKD2L1 | c.1675A>G p.I559V | Missense Mutation (SNP) | VAF 163/201 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58396202; called by muse, mutect2, varscan2
- PKP1 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.141); catalogued as COSV99825733; called by muse, mutect2
- PMEL | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 198/457 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62428708, COSV62428927; called by muse, mutect2, varscan2
- PPFIBP2 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1376234242, COSV55077448; called by muse, mutect2, varscan2
- PREPL | c.1167G>T p.W389C | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99576523; called by muse, mutect2
- RGS6 | c.960G>C p.E320D | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV100667058, COSV59596589; called by muse, mutect2
- SAMD12 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 206/538 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs751200165, COSV59050080; called by muse, mutect2, varscan2
- SCN4B | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 208/481 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV61252441; called by muse, mutect2, varscan2
- SETD1A | c.3460C>G p.P1154A | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV52688041; called by muse, mutect2, varscan2
- SLC19A2 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM121705, COSV52547392; called by muse, mutect2, varscan2
- SLC36A4 | c.1194G>T p.L398F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58396254; called by muse, mutect2, varscan2
- SLFN13 | c.2104C>G p.L702V | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53193679; called by muse, mutect2, varscan2
- STAT2 | c.1434C>A p.N478K | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV58475711; called by muse, mutect2, varscan2
- STON1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs147769896, COSV59131067; called by muse, mutect2, varscan2
- TAOK1 | c.2033T>C p.I678T | Missense Mutation (SNP) | VAF 89/106 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55592113; called by muse, mutect2, varscan2
- TCF20 | c.1519C>G p.P507A | Missense Mutation (SNP) | VAF 17/305 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371550964; called by muse, mutect2
- TM9SF4 | c.1837G>C p.V613L | Missense Mutation (SNP) | VAF 361/1259 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as COSV54107278, COSV99455095; called by muse, mutect2, varscan2
- TMEM71 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 82/419 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV63457486, COSV63459280; called by muse, mutect2, varscan2
- TMPRSS6 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60978631, COSV60979376; called by muse, mutect2, varscan2
- TOB2 | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV59501055; called by muse, mutect2, varscan2
- TRAPPC9 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 249/1438 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV66900178; called by muse, mutect2, varscan2
- TRPA1 | c.2241C>G p.N747K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV51562718; called by muse, mutect2, varscan2
- TSC2 | c.1194C>G p.N398K | Missense Mutation (SNP) | VAF 58/920 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99555457; called by muse, mutect2
- TTLL6 | c.1670C>T p.S557L (on ENST00000393382 / NM_001130918.3; = p.S250L on NM_173623.3) | Missense Mutation (SNP) | VAF 755/831 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs746768335, COSV64976189; called by muse, mutect2, varscan2
- UGT2A3 | c.1064T>A p.I355K | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs780768613, COSV99280239; called by muse, mutect2
- ZC3H18 | c.2750C>G p.T917S | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.097); catalogued as COSV56324840; called by muse, mutect2, varscan2
- ZNF648 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60571168; called by muse, mutect2, varscan2
- ZNF766 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63009640; called by muse, mutect2
- ZNF823 | c.626T>C p.L209S (on ENST00000341191 / NM_001297610.2; = p.L165S on NM_017507.2) | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.505); catalogued as rs748510172, COSV57873899; called by muse, mutect2, varscan2
- ARID2 | c.540_556del p.C180* | Frame Shift Del (DEL) | VAF 28/176 reads (16%) | called by mutect2, pindel, varscan2
- CYHR1 | c.154del p.A52Pfs*4 | Frame Shift Del (DEL) | VAF 106/144 reads (74%) | called by mutect2, varscan2
- KRT24 | c.63_81del p.G23Vfs*24 | Frame Shift Del (DEL) | VAF 56/68 reads (82%) | called by mutect2, pindel, varscan2
- OTUD7A | c.1613del p.N538Tfs*88 (on ENST00000307050 / NM_001382637.1; = p.N531Tfs*88 on NM_130901.3) | Frame Shift Del (DEL) | VAF 45/69 reads (65%) | called by mutect2, pindel, varscan2
- POU6F2 | c.402_426del p.G136Rfs*19 | Frame Shift Del (DEL) | VAF 29/52 reads (56%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.141); called by muse, mutect2
- ADGRE2 | c.627C>T p.V209= | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as rs1361099167, COSV100216534; called by muse, mutect2
- ALOX15B | c.1953C>T p.I651= | Silent (SNP) | VAF 129/163 reads (79%) | catalogued as COSV66479504; called by muse, mutect2, varscan2
- APOB | c.6540A>G p.Q2180= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV51936963; called by muse, mutect2, varscan2
- ARHGAP39 | c.1056G>A p.K352= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as COSV52770623; called by muse, mutect2, varscan2
- CNTN6 | c.663G>A p.V221= | Silent (SNP) | VAF 68/92 reads (74%) | catalogued as COSV63173480, COSV63195157; called by muse, mutect2, varscan2
- DGKI | c.1524C>T p.P508= | Silent (SNP) | VAF 149/476 reads (31%) | catalogued as rs779135844, COSV55951859; called by muse, mutect2, varscan2
- DUXA | c.360T>C p.F120= | Silent (SNP) | VAF 24/249 reads (10%) | catalogued as COSV73729715; called by muse, mutect2
- ELK1 | c.708G>T p.V236= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV55952996; called by muse, mutect2, varscan2
- EPHB4 | c.1659G>C p.L553= | Silent (SNP) | VAF 286/718 reads (40%) | catalogued as COSV62268948; called by muse, mutect2, varscan2
- FAM47B | c.1077C>T p.D359= | Silent (SNP) | VAF 87/189 reads (46%) | catalogued as rs770049861, COSV61453958; called by muse, mutect2, varscan2
- FOXP2 | c.253C>T p.L85= | Silent (SNP) | VAF 97/147 reads (66%) | catalogued as COSV63486671; called by muse, mutect2, varscan2
- ID4 | c.225G>A p.L75= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV66342994; called by muse, mutect2, varscan2
- IVNS1ABP | c.1398C>T p.Y466= | Silent (SNP) | VAF 53/104 reads (51%) | catalogued as rs1397159038, COSV62251153; called by muse, mutect2, varscan2
- NXF1 | c.1203A>C p.G401= | Silent (SNP) | VAF 26/409 reads (6%) | catalogued as COSV99586482; called by muse, mutect2
- OR5A1 | c.426C>T p.G142= | Silent (SNP) | VAF 199/585 reads (34%) | catalogued as COSV100118427, COSV57376835; called by muse, mutect2, varscan2
- PRADC1 | c.336G>C p.V112= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV57820336; called by muse, mutect2, varscan2
- PRDM15 | c.3474G>T p.G1158= | Silent (SNP) | VAF 211/488 reads (43%) | catalogued as COSV54153319; called by muse, mutect2, varscan2
- PREX1 | c.3927G>T p.L1309= | Silent (SNP) | VAF 65/848 reads (8%) | catalogued as COSV100906835; called by muse, mutect2
- RALY | c.114G>T p.V38= | Silent (SNP) | VAF 30/564 reads (5%) | catalogued as COSV99866228; called by muse, mutect2
- SIRT3 | c.120T>A p.L40= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV61501087; called by muse, mutect2, varscan2
- SLC22A6 | c.1137G>C p.L379= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as COSV64560295; called by muse, mutect2, varscan2
- TMED8 | c.672C>G p.T224= | Silent (SNP) | VAF 169/426 reads (40%) | catalogued as COSV53626426; called by muse, mutect2, varscan2
- TPCN2 | c.1869T>C p.C623= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as COSV53729329; called by muse, mutect2, varscan2
- WDR35 | c.2028A>T p.A676= (on ENST00000345530 / NM_001006657.2; = p.A665= on NM_020779.4) | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as COSV55603002; called by muse, mutect2, varscan2
- XKRX | c.1050C>T p.G350= | Silent (SNP) | VAF 114/251 reads (45%) | catalogued as COSV60708095; called by muse, mutect2, varscan2
- ZMYND15 | c.1089A>T p.A363= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV52641993; called by muse, mutect2, varscan2
- ZNF385A | c.816G>C p.S272= (on ENST00000338010 / NM_001130967.3; = p.S252= on NM_015481.3) | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV100567001; called by muse, mutect2
- ZNF574 | c.2616G>A p.V872= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV99726562; called by muse, mutect2
- FAM174C | c.*104G>C | 3'UTR (SNP) | VAF 138/165 reads (84%) | catalogued as COSV69703043; called by muse, mutect2, varscan2
- OR2W5 | n.1172C>G | RNA (SNP) | VAF 140/453 reads (31%) | called by muse, mutect2
